Somatic mutation profile of tumor specimen 0DIKK7 from CCDI case PBBSIH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.4 years (3,086 days).
Specimen 0DIKK7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5296134-55d4-48c6-8ff2-a763529ff404.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIKJC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ce1be77-41cf-4da1-bafb-4b06b4bf9246

The open-access MAF lists 13 somatic variants for this specimen: 4 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 3, In Frame Del 1, Intron 1, 5'Flank 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FMR1NB | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 30/632 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.096); catalogued as rs782545717, COSV65070953; called by muse, mutect2
- PTPRB | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 220/687 reads (32%) | SIFT tolerated, low confidence (0.44); PolyPhen possibly damaging (0.613); catalogued as rs1334317107, COSV99715073; called by muse, mutect2, varscan2
- HES1 | c.177_182del p.I61_L62del | In Frame Del (DEL) | VAF 300/1288 reads (23%) | called by mutect2, varscan2
- VEGFC | c.1246C>G p.P416A | Missense Mutation (SNP) | VAF 360/1294 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- CSNK2A1 | c.1158C>G p.A386= | Silent (SNP) | VAF 205/1037 reads (20%) | catalogued as COSV53935817; called by muse, mutect2, varscan2
- CXADR | c.324G>A p.T108= | Silent (SNP) | VAF 415/1273 reads (33%) | catalogued as rs758306077, COSV53028733; called by muse, mutect2, varscan2
- FMN1 | c.1674G>A p.K558= | Silent (SNP) | VAF 215/762 reads (28%) | called by muse, mutect2, varscan2
- PRKX | c.444G>A p.T148= | Silent (SNP) | VAF 190/532 reads (36%) | catalogued as rs1232597701, COSV53324044; called by muse, mutect2, varscan2
- SH2D3C | c.2250C>A p.I750= (on ENST00000314830 / NM_170600.3; = p.I593= on NM_005489.4) | Silent (SNP) | VAF 157/581 reads (27%) | called by muse, mutect2, varscan2
- LMAN2 | c.790+82C>A | Intron (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- PATE4 | c.-24G>A | 5'UTR (SNP) | VAF 161/467 reads (34%) | catalogued as rs757719981; called by muse, mutect2, varscan2
- PRR34 | n.291T>C | RNA (SNP) | VAF 196/572 reads (34%) | called by muse, mutect2, varscan2
- ZNF467 | chr7:149777707 ins C | 5'Flank (INS) | VAF 144/406 reads (35%) | called by mutect2, varscan2
